Somatic mutation profile of tumor specimen TCGA-EM-A3AL-01A (aliquot TCGA-EM-A3AL-01A-11D-A202-08) from TCGA case TCGA-EM-A3AL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 45.0 years (16,439 days).
Specimen TCGA-EM-A3AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8cdbdd0-0eee-4ab1-a4aa-580ba3be7345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AL-10A (Blood Derived Normal), aliquot TCGA-EM-A3AL-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef811901-ec76-4828-9843-fa8368f8a083

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53236298; called by muse, mutect2
- CDS2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV66897016; called by muse, mutect2, varscan2
- CSF2RA | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs190144821, COSV62625688; called by muse, mutect2
- DCT | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs913521450, COSV65470041; called by muse, mutect2, varscan2
- GAS1 | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53927545; called by muse, mutect2, varscan2
- OR2J2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs775420912, COSV65848084; called by muse, mutect2, varscan2
- RPL12 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV55941241; called by muse, mutect2
- ADSS1 | c.1221T>G p.P407= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV58274829; called by muse, mutect2
- DTNA | c.339C>T p.N113= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV52014113; called by muse, mutect2, varscan2
- MRPS30 | c.60C>T p.T20= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs774669607, COSV72361648; called by muse, mutect2, varscan2
- PRPS2 | c.630C>T p.D210= | Silent (SNP) | VAF 114/373 reads (31%) | catalogued as rs745704556, COSV66179717; called by muse, mutect2, varscan2
- RHBDL3 | c.459C>T p.Y153= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV52187660; called by muse, mutect2, varscan2
